Somatic mutation profile of tumor specimen 0DVSBV from CCDI case PBCNBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 3.7 years (1,363 days).
Specimen 0DVSBV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42aa12c3-2152-43e9-84aa-72e1e8d0af06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSC9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b615aaf-9acd-4761-9b5c-1a41164bc291

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 3, Frame Shift Del 3, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR6N1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 248/591 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58647327, COSV58650258; called by mutect2, varscan2
- PLEC | c.4098del p.Q1367Rfs*58 (on ENST00000322810 / NM_201380.4; = p.Q1257Rfs*58 on NM_000445.5) | Frame Shift Del (DEL) | VAF 144/446 reads (32%) | catalogued as COSV59663452; called by mutect2, varscan2
- TULP1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 200/351 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.374); catalogued as rs200344441, COSV57692988; called by muse, mutect2, varscan2
- VWC2 | c.938G>C p.R313P | Missense Mutation (SNP) | VAF 296/1677 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs375417945; called by muse, mutect2, varscan2
- ZNF479 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 212/1077 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1562846161; called by muse, mutect2, varscan2
- CAV1 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 265/1129 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.156); called by muse, varscan2
- CENPF | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 257/627 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by mutect2, varscan2
- CFAP161 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2
- DDX54 | c.2452C>G p.R818G | Missense Mutation (SNP) | VAF 142/635 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FTO | c.1140del p.R380Sfs*34 | Frame Shift Del (DEL) | VAF 190/407 reads (47%) | called by mutect2, varscan2
- GTF3A | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 199/1046 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KCNJ16 | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 257/577 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KDM7A | c.2642del p.P881Qfs*51 | Frame Shift Del (DEL) | VAF 234/1036 reads (23%) | called by mutect2, varscan2
- MINDY1 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 225/546 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MSR1 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 354/1431 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STX6 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 177/419 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TCERG1L | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- YDJC | c.951C>G p.F317L | Missense Mutation (SNP) | VAF 123/499 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF518B | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 233/629 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AMER1 | c.1788G>A p.R596= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- CBLN2 | c.564G>T p.V188= | Silent (SNP) | VAF 167/387 reads (43%) | called by muse, mutect2, varscan2
- FAM98C | c.693C>G p.L231= | Silent (SNP) | VAF 136/372 reads (37%) | called by muse, mutect2, varscan2
- KAT6A | c.2358C>T p.V786= | Silent (SNP) | VAF 354/1179 reads (30%) | catalogued as rs761721531, COSV55902811; called by muse, mutect2, varscan2
- IGFN1 | c.1241+309G>T | Intron (SNP) | VAF 129/256 reads (50%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-47152C>T | Intron (SNP) | VAF 250/559 reads (45%) | called by muse, mutect2, varscan2
- RBBP9 | c.-56A>T | 5'UTR (SNP) | VAF 153/331 reads (46%) | called by muse, mutect2, varscan2
- TFB1M | c.*47G>A | 3'UTR (SNP) | VAF 61/161 reads (38%) | catalogued as rs773445305; called by muse, mutect2, varscan2
- TMEM253 | c.108+26G>T | Intron (SNP) | VAF 100/217 reads (46%) | called by muse, mutect2, varscan2
- UBR4 | c.*14G>T | 3'UTR (SNP) | VAF 95/218 reads (44%) | called by muse, mutect2, varscan2
